Gene-level copy-number profile of tumor specimen TCGA-66-2790-01A from TCGA case TCGA-66-2790, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 72.3 years (26,420 days).
Specimen TCGA-66-2790-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.2ef96ca5-39f2-450b-bc45-b1d7ae6c30cf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-66-2790-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 824 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e237b1a9-e55d-4513-9aac-a24157346e64

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 86; copy number 2: 17,417; copy number 3: 2,576; copy number 4: 34,847; copy number 5: 1,534; copy number 6: 1,848; copy number 7: 110; copy number 8: 1,085; copy number 11: 114; copy number 17: 35; copy number 18: 54; copy number 27: 9; copy number 29: 15; copy number 38: 39.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-66-2790-01): tumor purity 0.57, ploidy 1.8, whole-genome doublings 0 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:81,501,794–81,557,702, 3 genes (within-gene range 0–2): ARID3BP1, AL138799.1, AL138799.3.
- chr2:140,898,423–141,208,376, 4 genes: LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.
- chr3:56,727,418–57,170,306, 6 genes (within-gene range 0–2): ARHGEF3, ARHGEF3-AS1, SPATA12, AC097358.2, IL17RD, AC097358.1.
- chr5:60,021,249–60,304,151, 2 genes: AC034234.1, RNU6-806P.
- chr8:3,373,353–3,426,587, 2 genes: AC026991.1, AC026991.2.
- chr8:4,496,392–4,635,654, 2 genes: AC010941.1, AC022068.1.
- chr9:27,937,617–27,944,497, 1 gene: AL353746.1.
- chr9:28,539,735–28,888,955, 4 genes: AL445526.1, KCTD10P1, MIR876, MIR873.
- chr11:80,321,620–80,528,066, 2 genes: AP006295.1, RNU6-544P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 117 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:68,707,440–71,818,238, 88 genes, copy number 18–38 (within-gene range 2–38) (broad region; genes not listed).
- chr18:26,204,869–27,595,164, 29 genes, copy number 18–27 (within-gene range 2–27): NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2.

Autosomal genes at a single copy (total copy number 1): 86. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
